Somatic mutation profile of tumor specimen MMRF_1929_1_BM_CD138pos (aliquot MMRF_1929_1_BM_CD138pos_T1_KHS5U_L08722) from MMRF case MMRF_1929, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.6 years (22,872 days).
Specimen MMRF_1929_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec11e64e-25bf-4c53-8c90-ccf8a4e31254.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1929_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1929_1_PB_Whole_C2_KHS5U_L08721; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eca3c283-20b6-4703-9342-bf6939a3bf01

The open-access MAF lists 103 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 28, Intron 14, Silent 12, 5'UTR 3, 3'Flank 3, 5'Flank 3, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 36/458 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- MAX | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 236/261 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM122946, COSV52415839; called by muse, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 30/107 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALOX15B | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.513); catalogued as COSV101205626; called by muse, mutect2, varscan2
- ASTN1 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs760721420, COSV62495360; called by muse, mutect2, varscan2
- COL17A1 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs766539630, COSV62226972; called by muse, mutect2, varscan2
- COL6A1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 282/538 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as rs149392243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIS3 | c.1400G>C p.R467P | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706858; called by muse, mutect2, varscan2
- FAT3 | c.12478G>A p.V4160M | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs1371147047; called by muse, mutect2, varscan2
- FAT4 | c.1880C>G p.T627S | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67882910; called by muse, mutect2, varscan2
- HAPLN4 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766288573; called by muse, mutect2, varscan2
- HMOX1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs766527808, COSV99330790; called by muse, mutect2, varscan2
- IKBKB | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs1064795873, COSV100645808, COSV60598802, COSV60598896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFBP | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs1362774155; called by muse, mutect2, varscan2
- MARK2 | c.1669C>T p.R557W (on ENST00000402010 / NM_001039469.2; = p.R523W on NM_017490.4) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1369739299; called by muse, mutect2, varscan2
- MAST4 | c.1921C>T p.R641C (on ENST00000403625 / NM_001164664.2; = p.R452C on NM_015183.3) | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774394019; called by muse, mutect2, varscan2
- MCF2 | c.1734C>A p.F578L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58478378; called by muse, mutect2, varscan2
- MYH3 | c.5462G>A p.R1821Q | Missense Mutation (SNP) | VAF 106/212 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as rs767892414, COSV104389031; called by muse, mutect2, varscan2
- PALLD | c.2394G>A p.M798I (on ENST00000505667 / NM_001166108.2; = p.M781I on NM_016081.4) | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs867880065; called by muse, mutect2, varscan2
- PCF11 | c.1400_1401del p.Q467Rfs*10 | Frame Shift Del (DEL) | VAF 100/262 reads (38%) | catalogued as rs1432552369, COSV53534586; called by mutect2, pindel, varscan2
- RYR2 | c.2974C>G p.Q992E | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV63699021; called by muse, mutect2, varscan2
- ANKRD11 | c.3576C>A p.D1192E | Missense Mutation (SNP) | VAF 206/418 reads (49%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD17 | c.4003T>A p.F1335I | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARID3C | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARIH1 | c.1500T>A p.N500K | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BLM | c.171_174dup p.V59Tfs*6 | Frame Shift Ins (INS) | VAF 64/145 reads (44%) | called by mutect2, pindel, varscan2
- CIITA | c.3107C>T p.A1036V | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COL11A1 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EVPL | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO9 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 171/382 reads (45%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- HAS1 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGSF10 | c.4223T>C p.I1408T | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- INO80D | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPFFR1 | c.1033C>G p.R345G | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PNMA1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SCAF8 | c.1611T>G p.Y537* | Nonsense Mutation (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- SLC30A10 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 53/428 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- SMTNL1 | c.988T>C p.F330L (on ENST00000399154; = p.F367L on NM_001105565.2) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SYTL5 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- TBC1D4 | c.3471A>T p.E1157D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ADAMTS5 | c.888C>A p.S296= | Silent (SNP) | VAF 79/158 reads (50%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.441G>A p.E147= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- CXorf21 | c.735C>T p.I245= | Silent (SNP) | VAF 10/199 reads (5%) | catalogued as COSV66762752; called by muse, mutect2
- DST | c.15561C>T p.F5187= (on ENST00000361203 / NM_001374722.1; = p.F2775= on NM_015548.5) | Silent (SNP) | VAF 108/208 reads (52%) | catalogued as rs763296327, COSV55009722; called by muse, mutect2, varscan2
- FLYWCH1 | c.228C>T p.L76= | Silent (SNP) | VAF 77/157 reads (49%) | catalogued as rs183328490, COSV54145389; called by muse, mutect2, varscan2
- H3C10 | c.261C>T p.S87= | Silent (SNP) | VAF 94/215 reads (44%) | catalogued as rs185076599; called by muse, mutect2, varscan2
- MYH14 | c.2277T>C p.D759= | Silent (SNP) | VAF 94/462 reads (20%) | called by muse, varscan2
- NXPE3 | c.1470A>G p.G490= | Silent (SNP) | VAF 96/389 reads (25%) | called by muse, mutect2, varscan2
- PLCD4 | c.1665G>A p.L555= | Silent (SNP) | VAF 72/143 reads (50%) | called by muse, mutect2, varscan2
- SPSB3 | c.411C>T p.A137= | Silent (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- TET2 | c.1416T>A p.P472= | Silent (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2, varscan2
- VCL | c.2271T>C p.A757= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- ABCE1 | c.*146T>C | 3'UTR (SNP) | VAF 79/624 reads (13%) | catalogued as COSV99668546; called by muse, mutect2, varscan2
- AL109984.1 | n.186+656C>G | Intron (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2
- AP000769.5 | chr11:65499248 G>A | 5'Flank (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*1867A>T | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by mutect2, varscan2
- ASRGL1 | c.*463G>A | 3'UTR (SNP) | VAF 48/110 reads (44%) | catalogued as rs192569201; called by muse, mutect2, varscan2
- B3GNT7 | c.*1561C>T | 3'UTR (SNP) | VAF 23/215 reads (11%) | catalogued as rs1036836203; called by muse, mutect2, varscan2
- CEP41 | c.98-4975G>C | Intron (SNP) | VAF 226/499 reads (45%) | called by muse, mutect2, varscan2
- COBLL1 | c.*5238A>G | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- DIPK2A | c.*2405C>G | 3'UTR (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- EXD2 | c.*862C>A | 3'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- FARP1 | c.171+31677_171+31687del | Intron (DEL) | VAF 31/40 reads (78%) | called by mutect2, pindel, varscan2
- FGG | c.*550T>A | 3'UTR (SNP) | VAF 164/535 reads (31%) | catalogued as COSV100271621; called by muse, mutect2, varscan2
- GFI1B | c.-701+77A>C | Intron (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- GLOD4 | chr17:783342 del A | 5'Flank (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- GMPPA | c.138+144del | Intron (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel
- GPAM | c.*3137G>A | 3'UTR (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- IP6K1 | c.*2262G>A | 3'UTR (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- ITGA1 | c.2772-82A>C | Intron (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- ITGA8 | c.2211+15G>C | Intron (SNP) | VAF 78/286 reads (27%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109964980 del TGAACT | 3'Flank (DEL) | VAF 28/236 reads (12%) | called by pindel, varscan2
- KCNV1 | chr8:109964991 T>G | 3'Flank (SNP) | VAF 26/230 reads (11%) | called by muse, varscan2
- KCNV1 | chr8:109966674 del TAAA | 3'Flank (DEL) | VAF 52/110 reads (47%) | called by mutect2, pindel, varscan2
- LACTB | c.*242T>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- LRRC4C | c.*66del | 3'UTR (DEL) | VAF 27/103 reads (26%) | called by mutect2, pindel, varscan2
- MRGPRG | chr11:3221924 G>A | 5'Flank (SNP) | VAF 135/298 reads (45%) | catalogued as rs1012415379; called by muse, mutect2, varscan2
- NDUFB6 | c.*697A>G | 3'UTR (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2
- NDUFB6 | c.-20G>A | 5'UTR (SNP) | VAF 110/254 reads (43%) | called by muse, mutect2, varscan2
- NFATC1 | c.2092+83A>T | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- NOP9 | c.*284T>G | 3'UTR (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- NOX5 | c.*1975G>A | 3'UTR (SNP) | VAF 26/195 reads (13%) | catalogued as rs949485570; called by muse, mutect2, varscan2
- POLD2 | c.1148-57G>A | Intron (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- PPP2R3B | c.1036+199C>T | Intron (SNP) | VAF 17/21 reads (81%) | catalogued as rs1395113314; called by muse, mutect2, varscan2
- PTP4A1 | c.*1861del | 3'UTR (DEL) | VAF 71/190 reads (37%) | called by mutect2, pindel, varscan2
- PUS7L | c.*1624G>T | 3'UTR (SNP) | VAF 64/117 reads (55%) | called by muse, mutect2, varscan2
- RBM43 | c.*996_*1010del | 3'UTR (DEL) | VAF 41/100 reads (41%) | called by mutect2, pindel, varscan2
- SLC12A2 | c.*2357C>T | 3'UTR (SNP) | VAF 68/163 reads (42%) | called by muse, mutect2, varscan2
- SLC22A11 | c.*802C>T | 3'UTR (SNP) | VAF 51/115 reads (44%) | catalogued as rs1192894639; called by muse, mutect2, varscan2
- SLC25A18 | c.-55C>T | 5'UTR (SNP) | VAF 52/113 reads (46%) | catalogued as rs1235747275; called by muse, mutect2, varscan2
- SPA17 | c.*2833G>T | 3'UTR (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- SPAST | c.*806T>C | 3'UTR (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- TBC1D20 | c.*177del | 3'UTR (DEL) | VAF 61/165 reads (37%) | called by mutect2, pindel, varscan2
- TBL3 | c.*1622C>T | 3'UTR (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- THRA | c.1110+1511_1110+1515del | Intron (DEL) | VAF 96/213 reads (45%) | called by mutect2, pindel, varscan2
- TMC2 | c.*194C>G | 3'UTR (SNP) | VAF 71/173 reads (41%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+239C>T | Intron (SNP) | VAF 49/52 reads (94%) | called by muse, mutect2, varscan2
- UST | c.-34C>A | 5'UTR (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- VSTM2L | c.*918T>C | 3'UTR (SNP) | VAF 55/123 reads (45%) | called by muse, mutect2, varscan2
- VWA5B2 | c.530+88T>C | Intron (SNP) | VAF 107/228 reads (47%) | called by muse, mutect2, varscan2
- WDR36 | c.*1926C>T | 3'UTR (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- ZMYM6 | c.428+231A>G | Intron (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- ZNF525 | c.*3540T>C | 3'UTR (SNP) | VAF 8/65 reads (12%) | catalogued as rs1205275534; called by muse, mutect2, varscan2
